Surgical pathology report (de-identified scan), TCGA case TCGA-43-2576, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-2576-01A (Primary Tumor).

SPECIMEN

- A. Level 5 lymph node
- B. Left upper lobe
- C. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer

FROZEN SECTION DIAGNOSIS

- A) Lymph node, level 5, excision - Non small cell carcinoma.

GROSS DESCRIPTION

A. Received fresh for frozen section labeled "level 5 lymph node" is an irregularly shaped fragment of tissue that measures 2.5 x 2.2 x 1.5 cm in dimension. A representative section of the tissue submitted for frozen section. The remaining tissue is entirely submitted for permanent section in a single cassette.

B. Received fresh, subsequently fixed in formalin labeled "left upper lobe" is a 14.5 x 5.5 x 4.0 cm lung specimen which is partially covered with pink-red smooth glistening pleura with black stippling present. The specimen shows a umbilication in the pleura which is 1.2 cm in greatest dimension and comes within 3.0 cm of the stapled margin. The pleura is inked blue and black and the specimen is sectioned to show a 3.5 x 2.5 x 2.5 cm white-tan-gray firm focus grossly consistent with tumor. This is contiguous with the umbilication grossly identified on the pleura and comes within 0.7 cm of the stapled margin (inked blue). Remainder of the cut surface is pink-tan and spongy showing no other

discrete gross lesions identified. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1 - representative normal; 2-3 - representative section tumor to stapled margin; 4-6 - representative section of

GROSS DESCRIPTION

tumor to pleura and normal.

C. Received fresh, subsequently fixed in formalin, labeled

"level 7" are two black-red irregular soft tissue fragments

measuring 0.8 cm and 0.6 cm in greatest dimension. Specimens are entirely submitted in one cassette.

Source: NCI Genomic Data Commons file 44fcbf92-22cc-47f6-a3f0-6ec186656804 (TCGA-43-2576.15A1F3EB-1B46-45C4-85F8-0D52710986B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).